Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACE-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

1. Specimen:
Liver: 13.0 x 7.5 x 4.5 cm, 185.0 gm, unfixed
2. Tumor location: segment 8
Tumor number: one
Tumor size: 4.0 x 3.0 x 3.8 cm
3. Satellite nodule: no
4. Gross type
HCC: expanding nodular
5. Tumor necrosis: no
6. Hemorrhage/peliosis: no
7. Portal vein invasion: no
8. Bile duct invasion: no

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JAD 5/19/14

Gross photo present.

Blocks

TB, T1-4, tumor mass x 5
RM, resection margin x 1
NB, A, non-tumorous liver parenchyme x 2

MICROSCOPIC:

1. Hepatocellular carcinoma: yes
- 1-1. Differentiation
The worst differentiation III
The major differentiation II
- 1-2. Histologic type: trabecular, pseudoglandular
- 1-3. Cell type: hepatic
- 1-4. Fatty change: no
2. Fibrous capsule formation: complete capsule
3. Capsular infiltration: no
4. Septum formation: no
5. Surgical resection margin invasion: no, margin of the clearance (1.0 cm)
6. Serosal invasion: no
7. Portal vein invasion: no
8. Bile duct invasion: no

[page 2 of 2]
9. Hepatic vein invasion: no
10. Hepatic artery invasion: no
11. Microvessel invasion: no
12. Intrahepatic metastasis: no
13. Multicentric occurrence: no

Non-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: minimal
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN: Trichrome (+ stage (3-4))

NOT reported. Gross:

Tunica vaginalis, inguinal, ligation, Hernial sac

Stomach, angle, scopic, chronic gastritis, H. pylori, associated

Stomach, angle, scopic, ulcer

Liver, ectomy, hepatocellular carcinoma, cirrhosis
T56000, P10, M81703, M49500

DIAGNOSIS:

Liver, segment 8, segmentectomy:
Hepatocellular carcinoma, moderately differentiated
Cirrhosis, micronodular

Suggestion :

Source: NCI Genomic Data Commons file d9a7677b-2eec-4e84-bc3b-9bca8a456599 (TCGA-DD-AACE.63AE7F04-F180-486A-89FB-6E509AF91E0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).